Surgical pathology report (de-identified scan), TCGA case TCGA-G7-A8LE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-A8LE-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site of Kidney NOS
C64.9
JW 11/24/13

SPECIMENS:

A. LEF TPARTIAL NEPHRECTOMY

SPECIMEN(S):

A. LEF TPARTIAL NEPHRECTOMY

DIAGNOSIS:

- A. KIDNEY, LEFT, PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE
- FUHRMAN GRADE: 2
- TUMOR SIZE: 4 x 3.8 x 3 CM
- TUMOR LIMITED TO THE KIDNEY
- SURGICAL MARGIN FOCALLY POSITIVE (0.1 CM)

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: LEF TPARTIAL NEPHRECTOMY

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 4cm

Additional dimensions: 3.8cm x 3cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u; nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margin(s) involved by invasive carcinoma

Include: Renal parenchymal margin (partial nephrectomy only)

Distance: 0cm

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: Glomerular disease

type: GLOMERULOSCLEROSIS

Pathological Staging (pTNM): pT 1a N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

PMX: Cannot be assessed

GROSS DESCRIPTION:

A. LEFT PARTIAL NEPHRECTOMY

fresh labeled with the patient's identification and designated "left partial nephrectomy" is a ruptured partial nephrectomy specimen with attached perirenal adipose tissue weighing 31 g and measuring 9.5 x 4 x 3.5 cm. A suture designates the surgical resection margin, inked blue (remainder of the specimen inked black). The specimen is sectioned to show an ill-defined, soft, 4 x 3.8 x 3 cm mass with heterogeneous, focally hemorrhagic cut surface approaching the surgical resection margin at 0.1 cm. The mass grossly involves the surrounding adipose tissue. Gross photograph is taken. A portion of the specimen is submitted for tissue procurement. Representative sections are submitted:

A1-A4: Mass, surgical resection margin

A5-A6: Mass, disrupted area

A7-A8: Mass, adipose tissue

[page 2 of 2]
CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

Gross Dictation:.

Microscopic/Diagnostic Dictation:

Final Review: Pathologist,

Final:., Pathologist,

Source: NCI Genomic Data Commons file 0aa6302c-8049-4f5a-a0d5-f4a5ada9a5c7 (TCGA-G7-A8LE.81B3FE6C-B158-4165-9E26-DB95B9D6FC9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).